Somatic mutation profile of tumor specimen 0DRCK0 from CCDI case PBCFYZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,393 days).
Specimen 0DRCK0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc96828-c0b3-435a-ab20-ab49e56f0027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRCJY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20558eb4-7c78-49c9-bc98-fac2d1193b4c

The open-access MAF lists 46 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Intron 6, 5'UTR 3, Nonsense Mutation 3, Splice Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 34/720 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- ALG13 | c.3406G>C p.G1136R | Missense Mutation (SNP) | VAF 213/337 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs376207448, COSV99321560; called by muse, mutect2, varscan2
- ANO2 | c.559G>A p.A187T (on ENST00000356134 / NM_001278597.3; = p.A191T on NM_001278596.3) | Missense Mutation (SNP) | VAF 174/445 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs763491972, COSV59047889; called by muse, mutect2, varscan2
- APC | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 446/1068 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730881233, COSV57333293; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COX18 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 408/896 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs1343362812, COSV55720549; called by muse, varscan2
- CROCC2 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 140/353 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1007597766; called by muse, mutect2, varscan2
- ESR1 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 58/766 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs751407371, COSV52791925; called by muse, mutect2
- ESYT1 | c.3271C>T p.R1091W | Missense Mutation (SNP) | VAF 253/574 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs767546962; called by muse, mutect2, varscan2
- KRT39 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 67/1814 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.918); catalogued as rs530818487, COSV62918011; called by muse, mutect2
- MLLT3 | c.398G>C p.R133T | Missense Mutation (SNP) | VAF 424/1322 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as COSV63497387; called by muse, mutect2, varscan2
- PKD1L1 | c.8006G>A p.R2669Q | Missense Mutation (SNP) | VAF 639/1028 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs369504382; called by muse, mutect2, varscan2
- SLC45A1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 186/416 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs147681901; called by muse, mutect2, varscan2
- ZC3H13 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 154/736 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs776281684, COSV54448054; called by muse, mutect2, varscan2
- ABCB1 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 1100/1782 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- ARHGAP27 | c.2276G>A p.G759E (on ENST00000428638 / NM_001282290.1; = p.G418E on NM_199282.3) | Missense Mutation (SNP) | VAF 46/966 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BMX | c.768A>T p.E256D | Missense Mutation (SNP) | VAF 74/611 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 32/990 reads (3%) | called by muse, mutect2
- COA7 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 447/940 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMCN | c.125C>T p.T42I | Missense Mutation (SNP) | VAF 543/1334 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GRK3 | c.1024T>C p.F342L | Missense Mutation (SNP) | VAF 99/1657 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.431); called by muse, mutect2
- HSPG2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 112/244 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- NAGPA | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 149/319 reads (47%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OBI1 | c.2134C>T p.Q712* | Nonsense Mutation (SNP) | VAF 52/1626 reads (3%) | called by muse, mutect2
- PDE4DIP | c.5703C>A p.C1901* | Nonsense Mutation (SNP) | VAF 78/1603 reads (5%) | called by muse, mutect2
- PRR22 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 47/514 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SMG7 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 199/554 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TREML1 | c.44-2A>T p.X15_splice | Splice Site (SNP) | VAF 66/221 reads (30%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1395G>C p.Q465H | Missense Mutation (SNP) | VAF 199/506 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HDAC9 | c.2001A>C p.R667= | Silent (SNP) | VAF 468/1686 reads (28%) | catalogued as rs532517909; called by muse, mutect2, varscan2
- IL17RC | c.831C>T p.C277= (on ENST00000295981 / NM_153461.4; = p.C206= on NM_153460.4) | Silent (SNP) | VAF 56/724 reads (8%) | called by muse, mutect2
- JPH2 | c.810C>T p.A270= | Silent (SNP) | VAF 68/612 reads (11%) | catalogued as rs779680763; called by muse, mutect2
- OR56A4 | c.249T>A p.S83= | Silent (SNP) | VAF 322/355 reads (91%) | called by muse, mutect2, varscan2
- ST7L | c.1242A>C p.P414= | Silent (SNP) | VAF 68/612 reads (11%) | called by muse, mutect2, varscan2
- TRAPPC11 | c.2940G>C p.G980= | Silent (SNP) | VAF 32/1200 reads (3%) | called by muse, mutect2
- ZFHX4 | c.3267A>G p.P1089= | Silent (SNP) | VAF 583/1327 reads (44%) | catalogued as rs750900153; called by muse, mutect2, varscan2
- ADGRL2 | c.-57G>A | 5'UTR (SNP) | VAF 121/258 reads (47%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 32/508 reads (6%) | called by muse, mutect2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 32/494 reads (6%) | called by muse, mutect2
- CD300LD | c.40+14G>A | Intron (SNP) | VAF 50/1666 reads (3%) | catalogued as rs1445282270; called by muse, mutect2
- COL4A2 | c.1340-266C>T | Intron (SNP) | VAF 407/1594 reads (26%) | called by muse, varscan2
- EBF3 | c.913-10G>A | Intron (SNP) | VAF 224/704 reads (32%) | called by muse, mutect2, varscan2
- IRGM | c.-66T>C | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 26/400 reads (7%) | called by muse, mutect2
- MAPT | c.*63dup | 3'UTR (INS) | VAF 86/269 reads (32%) | catalogued as rs1278350113; called by mutect2, varscan2
- PPHLN1 | c.1126-179G>T | Intron (SNP) | VAF 16/131 reads (12%) | called by muse, varscan2
- PPM1E | c.-93C>A | 5'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2
